Somatic mutation profile of tumor specimen C3L-00963-01 (aliquot CPT0016490006) from CPTAC case C3L-00963, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 59.7 years (21,815 days).
Specimen C3L-00963-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc2eb823-8219-4049-bfc0-d5f665e1f2f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00963-71 (Blood Derived Normal), aliquot CPT0016580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c589d84-1dae-47c7-8ac6-50ca92f25b6d

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 9, 5'UTR 2, Intron 2, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- SOS1 | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1553362937, CM100895, COSV67676900; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.437G>A p.W146* | Nonsense Mutation (SNP) | VAF 44/198 reads (22%) | hotspot (GDC flag); catalogued as rs1206165503, CM107391, COSV52661900, COSV52703354, COSV52753201; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASCC3 | c.4697G>C p.R1566P | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64982138; called by muse, mutect2, varscan2
- ASPM | c.8287G>C p.E2763Q | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV54124544, COSV54136194; called by muse, mutect2, varscan2
- BRSK1 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 93/501 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1231206905, COSV58667459; called by muse, mutect2, varscan2
- CBLN4 | c.71C>A p.P24H | Missense Mutation (SNP) | VAF 88/265 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.237); catalogued as rs746116052; called by muse, mutect2, varscan2
- CNTN6 | c.2253G>T p.E751D | Missense Mutation (SNP) | VAF 53/210 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV63167892, COSV63177366; called by muse, varscan2
- DLGAP2 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.808); catalogued as rs771718672, COSV101422634; called by muse, mutect2, varscan2
- ETV2 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 101/450 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as rs1300677837, COSV99876791; called by muse, mutect2, varscan2
- FAM120C | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1557137712; called by muse, varscan2
- FIGN | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs766943714, COSV104411568, COSV60764351; called by muse, mutect2, varscan2
- HYDIN | c.6772C>T p.R2258W | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751267096, COSV99992109; called by muse, mutect2, varscan2
- KCNH4 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.092); catalogued as COSV52920690; called by muse, mutect2, varscan2
- NGFR | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as rs927479330; called by muse, mutect2, varscan2
- NRG3 | c.2111C>T p.A704V (on ENST00000404547 / NM_001370084.1; = p.A680V on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.666); catalogued as rs367831182; called by muse, mutect2, varscan2
- PXDN | c.2228C>T p.T743M | Missense Mutation (SNP) | VAF 235/562 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs758592134, COSV53238571; called by muse, mutect2, varscan2
- RRAS2 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 387/552 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56329970, COSV56331263; called by muse, mutect2, varscan2
- SATB2 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 74/410 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs751765693; called by muse, varscan2
- SEZ6L2 | c.1444C>T p.R482C (on ENST00000308713 / NM_001114099.3; = p.R412C on NM_012410.4) | Missense Mutation (SNP) | VAF 33/252 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs1466762799, COSV58096772; called by muse, mutect2, varscan2
- SKI | c.1463G>A p.S488N | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs763580567; called by muse, mutect2, varscan2
- TENM1 | c.8075G>C p.G2692A | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV64430362; called by muse, mutect2, varscan2
- TRAPPC11 | c.3074G>A p.R1025H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.973); catalogued as rs374203755; called by muse, mutect2, varscan2
- UPF3B | c.1118G>A p.R373H (on ENST00000276201 / NM_080632.3; = p.R360H on NM_023010.3) | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.858); catalogued as rs146785878; ClinVar: uncertain significance; called by muse, varscan2
- ZFPM1 | c.2993C>T p.S998F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs753287725; called by muse, mutect2
- ZNF248 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as rs1449397934, COSV61998227; called by muse, mutect2, varscan2
- ARHGAP35 | c.760del p.T254Qfs*17 | Frame Shift Del (DEL) | VAF 27/167 reads (16%) | called by mutect2, pindel, varscan2
- ARR3 | c.312G>T p.K104N | Missense Mutation (SNP) | VAF 51/258 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP2A2 | c.1448_1452del p.F483Sfs*6 | Frame Shift Del (DEL) | VAF 47/243 reads (19%) | called by mutect2, pindel, varscan2
- C20orf194 | c.738dup p.D247* | Frame Shift Ins (INS) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- CDH19 | c.1649T>A p.I550N | Missense Mutation (SNP) | VAF 57/231 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- EPYC | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FGFR1 | c.1247A>G p.K416R (on ENST00000447712 / NM_023110.3; = p.K414R on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/836 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- KCNA5 | c.1617G>T p.Q539H | Missense Mutation (SNP) | VAF 63/343 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KMT2E | c.2329C>T p.L777F | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- LRPPRC | c.3178G>A p.E1060K | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- POGK | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 38/193 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RICTOR | c.3207G>T p.E1069D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by mutect2, varscan2
- RPS3 | c.629T>C p.I210T | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- STMP1 | c.114G>T p.L38F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- STMP1 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- VPS26B | c.864G>C p.Q288H | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF729 | c.563C>A p.S188* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- ZNF860 | c.1605G>T p.E535D | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- ABCD1 | c.657C>G p.L219= | Silent (SNP) | VAF 40/239 reads (17%) | called by muse, mutect2, varscan2
- ADGRB2 | c.1731G>A p.A577= | Silent (SNP) | VAF 27/242 reads (11%) | catalogued as rs370752253; called by muse, mutect2, varscan2
- AKAP9 | c.9858T>A p.L3286= (on ENST00000359028; = p.L3262= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/139 reads (32%) | called by muse, mutect2, varscan2
- CEP104 | c.1296C>T p.I432= | Silent (SNP) | VAF 64/278 reads (23%) | catalogued as rs1003073399, COSV65517887; called by muse, mutect2, varscan2
- GRM1 | c.3537C>T p.Y1179= | Silent (SNP) | VAF 123/740 reads (17%) | catalogued as COSV99264339; called by muse, mutect2, varscan2
- MAP7D3 | c.699G>A p.S233= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs770233543, COSV60170216; called by muse, mutect2, varscan2
- MUC5B | c.8493C>A p.G2831= | Silent (SNP) | VAF 149/609 reads (24%) | catalogued as rs746206778; called by muse, mutect2, varscan2
- OCA2 | c.2322C>T p.F774= | Silent (SNP) | VAF 78/454 reads (17%) | catalogued as rs762388937, COSV100668544; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121 | c.3102G>A p.T1034= (on ENST00000434423; = p.T769= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as rs139238552; called by muse, mutect2
- GALNT3 | c.-36C>T | 5'UTR (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- LAMA3 | c.1603+11924A>G | Intron (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2, varscan2
- MECP2 | c.-192G>A | 5'UTR (SNP) | VAF 6/29 reads (21%) | called by muse, mutect2
- TTN | c.10360+1369C>T | Intron (SNP) | VAF 8/47 reads (17%) | catalogued as rs201047740, COSV60013858; ClinVar: uncertain significance; called by muse, mutect2, varscan2
